Somatic mutation profile of tumor specimen MP2PRT-PAPANB-TMP1-A (aliquot MP2PRT-PAPANB-TMP1-A-1-0-D-A83L-36) from MP2PRT case MP2PRT-PAPANB, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.9 years (2,173 days).
Specimen MP2PRT-PAPANB-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 44b2655b-5397-4b17-a3b1-ed58bd23c027.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPANB-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPANB-NB1-A-1-0-D-A83L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f0221f1-7693-4e48-9b7a-eb070ad8ce27

The open-access MAF lists 30 somatic variants for this specimen: 20 protein-altering or splice-affecting, 9 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 9, In Frame Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FMN1 | c.2828C>T p.P943L (on ENST00000616417 / NM_001277313.2; = p.P720L on NM_001103184.4) | Missense Mutation (SNP) | VAF 68/192 reads (35%) | SIFT tolerated (0.87); PolyPhen possibly damaging (0.652); catalogued as rs772209223, COSV57927031; called by muse, mutect2, varscan2
- GALNT18 | c.1351C>T p.R451W | Missense Mutation (SNP) | VAF 81/186 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs376689514; called by muse, mutect2, varscan2
- GREB1L | c.787G>A p.E263K | Missense Mutation (SNP) | VAF 52/258 reads (20%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.987); catalogued as COSV52566313; called by muse, mutect2, varscan2
- GSN | c.586C>T p.R196C | Missense Mutation (SNP) | VAF 114/413 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1246783224; called by muse, mutect2, varscan2
- KRT34 | c.1028C>T p.T343M | Missense Mutation (SNP) | VAF 56/301 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs143564749; called by muse, mutect2, varscan2
- LIFR | c.2795G>A p.R932H | Missense Mutation (SNP) | VAF 124/447 reads (28%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as rs756414449, COSV54700169; called by muse, mutect2, varscan2
- PLCB3 | c.3674C>T p.S1225L | Missense Mutation (SNP) | VAF 142/320 reads (44%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs778033643; called by muse, mutect2, varscan2
- SCN3A | c.2421G>A p.M807I | Missense Mutation (SNP) | VAF 86/186 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV51825823; called by muse, mutect2, varscan2
- SLC34A2 | c.1511C>T p.P504L | Missense Mutation (SNP) | VAF 77/282 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV65941730; called by muse, mutect2, varscan2
- THNSL2 | c.665C>T p.S222L | Missense Mutation (SNP) | VAF 99/252 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs964320373, COSV59084671; called by muse, mutect2, varscan2
- TRDN | c.860G>A p.S287N | Missense Mutation (SNP) | VAF 88/285 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs772876323; called by muse, mutect2, varscan2
- AEBP2 | c.1499G>A p.R500K | Missense Mutation (SNP) | VAF 33/93 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); called by muse, mutect2, varscan2
- CREBBP | c.4460A>T p.H1487L | Missense Mutation (SNP) | VAF 110/309 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GRIK2 | c.1589C>T p.S530F | Missense Mutation (SNP) | VAF 92/328 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MYO18B | c.3958C>T p.L1320F | Missense Mutation (SNP) | VAF 77/159 reads (48%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- POLR3C | c.297_305del p.S100_T102del | In Frame Del (DEL) | VAF 84/200 reads (42%) | called by mutect2, pindel, varscan2
- SPOCD1 | c.2870G>A p.G957E | Missense Mutation (SNP) | VAF 121/328 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TUBA3D | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 24/214 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); called by muse, varscan2
- TUBA3E | c.694G>A p.G232R | Missense Mutation (SNP) | VAF 140/549 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); called by muse, varscan2
- USP9X | c.5694T>G p.Y1898* | Nonsense Mutation (SNP) | VAF 16/246 reads (7%) | called by muse, mutect2
- ARHGAP36 | c.1074C>T p.C358= | Silent (SNP) | VAF 123/268 reads (46%) | called by muse, mutect2, varscan2
- CLRN1 | c.48C>T p.F16= | Silent (SNP) | VAF 116/270 reads (43%) | called by muse, mutect2, varscan2
- CNGA2 | c.1101C>T p.I367= | Silent (SNP) | VAF 151/335 reads (45%) | catalogued as rs141471697, COSV61704820; called by muse, mutect2, varscan2
- COL4A2 | c.2397C>T p.P799= | Silent (SNP) | VAF 108/243 reads (44%) | catalogued as rs890625154; called by muse, mutect2, varscan2
- CYP3A7 | c.1350G>A p.V450= | Silent (SNP) | VAF 129/284 reads (45%) | called by muse, mutect2, varscan2
- FASN | c.1590C>T p.F530= | Silent (SNP) | VAF 125/252 reads (50%) | catalogued as rs373355785; called by muse, mutect2, varscan2
- FSHR | c.2004G>A p.R668= | Silent (SNP) | VAF 95/240 reads (40%) | catalogued as COSV58633859; called by muse, mutect2, varscan2
- OR51V1 | c.411C>T p.S137= | Silent (SNP) | VAF 77/198 reads (39%) | called by muse, mutect2, varscan2
- SOGA3 | c.2286C>T p.S762= | Silent (SNP) | VAF 171/552 reads (31%) | catalogued as rs757258840, COSV64107043; called by muse, mutect2, varscan2
- PENK | c.138+86G>A | Intron (SNP) | VAF 153/503 reads (30%) | catalogued as rs751969004, COSV100152544; called by muse, mutect2, varscan2
